Somatic mutation profile of tumor specimen TCGA-D6-6825-01A (aliquot TCGA-D6-6825-01A-21D-1912-08) from TCGA case TCGA-D6-6825, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 73.9 years (26,976 days).
Specimen TCGA-D6-6825-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6556aad0-1fed-4933-aea8-7720ecb09345.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D6-6825-10A (Blood Derived Normal), aliquot TCGA-D6-6825-10A-01D-1912-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1790a1ad-de72-45c4-bb54-069a5b7d3017

The open-access MAF lists 76 somatic variants for this specimen: 53 protein-altering or splice-affecting, 22 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 43, Silent 22, Nonsense Mutation 6, Frame Shift Del 2, Splice Region 1, 3'UTR 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.358G>T p.E120* | Nonsense Mutation (SNP) | VAF 19/45 reads (42%) | hotspot (GDC flag); catalogued as CD972119, COSV58683444, COSV58717600; called by muse, mutect2, varscan2
- TP53 | c.559+2T>G p.X187_splice | Splice Site (SNP) | VAF 21/53 reads (40%) | hotspot (GDC flag); catalogued as CS114004, COSV52709511, COSV52900265, COSV53486980, COSV99478821; called by muse, mutect2, varscan2
- ABCA10 | c.3346C>G p.L1116V | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.055); catalogued as COSV99288923; called by muse, mutect2, varscan2
- ADAM29 | c.1714C>A p.H572N | Missense Mutation (SNP) | VAF 23/135 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV100822104; called by muse, mutect2, varscan2
- ATAD2 | c.3656G>A p.G1219E | Missense Mutation (SNP) | VAF 28/126 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0.006); catalogued as COSV99784964; called by muse, mutect2, varscan2
- AXDND1 | c.1832C>G p.S611C | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.015); catalogued as COSV100858522; called by muse, mutect2, varscan2
- C3orf38 | c.163C>T p.Q55* | Nonsense Mutation (SNP) | VAF 8/41 reads (20%) | catalogued as COSV100007438; called by muse, varscan2
- CCDC198 | c.757C>T p.Q253* | Nonsense Mutation (SNP) | VAF 5/59 reads (8%) | catalogued as COSV99371300; called by muse, mutect2
- CCDC50 | c.878G>A p.G293E | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.466); catalogued as rs868041774, COSV101165327; called by muse, mutect2, varscan2
- CD163L1 | c.3980C>T p.A1327V | Missense Mutation (SNP) | VAF 38/133 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.875); catalogued as COSV100550335; called by muse, mutect2, varscan2
- CHCHD4 | c.236C>T p.T79M (on ENST00000396914 / NM_001098502.2; = p.T92M on NM_144636.3) | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.708); catalogued as rs758658272, COSV99853876; called by muse, mutect2, varscan2
- CLIC1 | c.643G>A p.A215T | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs764853833, COSV101007526; called by muse, mutect2, varscan2
- CLSTN3 | c.1099C>A p.Q367K | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT tolerated (0.87); PolyPhen benign (0.027); catalogued as COSV99867311; called by muse, mutect2, varscan2
- COBLL1 | c.2836C>T p.Q946* (on ENST00000392717; = p.Q908* on NM_014900.5) | Nonsense Mutation (SNP) | VAF 14/60 reads (23%) | catalogued as COSV99528305; called by muse, mutect2, varscan2
- COL14A1 | c.2038A>G p.I680V | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs1563683296, COSV99919860; called by muse, mutect2, varscan2
- DOCK1 | c.4363G>A p.A1455T | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.32); catalogued as COSV99731005; called by muse, mutect2, varscan2
- EME1 | c.17C>T p.S6L | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); catalogued as COSV99869016; called by muse, mutect2, varscan2
- ENPP1 | c.2293A>T p.M765L | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.897); catalogued as COSV100719596; called by muse, mutect2, varscan2
- FAM71B | c.256G>A p.V86I | Missense Mutation (SNP) | VAF 20/104 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.536); catalogued as rs376135369; called by muse, mutect2, varscan2
- FAXDC2 | c.232C>T p.L78F | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.798); catalogued as COSV100394269, COSV58172564; called by muse, mutect2, varscan2
- GABRB3 | c.320C>T p.T107M | Missense Mutation (SNP) | VAF 21/100 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1347499222, COSV54661500, COSV54683742; called by muse, mutect2, varscan2
- GLCCI1 | c.766C>T p.R256C | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.011); catalogued as rs774566628, COSV56201914; called by mutect2, varscan2
- GRXCR1 | c.675C>G p.D225E | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.987); catalogued as COSV101295718; called by muse, mutect2, varscan2
- GSN | c.2048A>G p.E683G | Missense Mutation (SNP) | VAF 36/78 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100376400; called by muse, mutect2, varscan2
- HTRA2 | c.545G>T p.G182V | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99239785; called by muse, mutect2, varscan2
- KCTD15 | c.262G>A p.G88S | Missense Mutation (SNP) | VAF 20/156 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.71); catalogued as COSV99393272; called by muse, mutect2, varscan2
- LGALSL | c.352T>C p.F118L | Missense Mutation (SNP) | VAF 40/227 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99482486; called by muse, mutect2, varscan2
- MAPRE3 | c.532G>A p.V178M | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.021); catalogued as rs943139821, COSV51866570; called by muse, mutect2, varscan2
- MYC | c.437C>T p.S146L (on ENST00000377970; = p.S161L on NM_002467.6) | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV52367052; called by muse, mutect2, varscan2
- NLGN1 | c.1765G>T p.G589* | Nonsense Mutation (SNP) | VAF 9/81 reads (11%) | catalogued as COSV100849627; called by muse, mutect2, varscan2
- NLRP5 | c.463G>C p.E155Q | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.106); catalogued as rs1568483598, COSV101173777; called by muse, mutect2
- NUSAP1 | c.436G>A p.A146T | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.42); PolyPhen benign (0.094); catalogued as COSV99530983; called by muse, mutect2, varscan2
- OR9A4 | c.794C>T p.T265M | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.738); catalogued as COSV71885570; called by muse, mutect2, varscan2
- PCDHB13 | c.1894G>T p.E632* | Nonsense Mutation (SNP) | VAF 17/109 reads (16%) | catalogued as rs868928753, COSV99507506; called by muse, mutect2, varscan2
- PGAP2 | c.709G>A p.D237N (on ENST00000463452 / NM_001346398.2; = p.D298N on NM_014489.4) | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99544437; called by muse, mutect2, varscan2
- PLXDC2 | c.491A>G p.D164G | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.045); catalogued as rs764685614, COSV101023103; called by muse, mutect2, varscan2
- PTCH1 | c.2275G>C p.G759R | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.56); catalogued as COSV100109228; called by muse, mutect2, varscan2
- PTCHD1 | c.2269T>G p.L757V | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.842); catalogued as COSV101037841; called by muse, mutect2, varscan2
- RBMS3 | c.1305T>C p.S435= (on ENST00000383767 / NM_001003793.3; = p.S419= on NM_014483.3) | Splice Region (SNP) | VAF 16/73 reads (22%) | catalogued as COSV99822727; called by muse, mutect2, varscan2
- SCML2 | c.619G>A p.D207N | Missense Mutation (SNP) | VAF 55/136 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99319199; called by muse, mutect2, varscan2
- SEMA6A | c.307G>A p.D103N | Missense Mutation (SNP) | VAF 17/113 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); catalogued as rs759696349, COSV57319534; called by muse, mutect2, varscan2
- SLC9C2 | c.2446C>A p.L816I | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.393); catalogued as rs200464845, COSV100876864; called by muse, mutect2, varscan2
- SYNE1 | c.9035C>G p.A3012G (on ENST00000367255 / NM_182961.4; = p.A3019G on NM_033071.3) | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.706); catalogued as COSV99571059; called by muse, mutect2, varscan2
- TANGO6 | c.1355G>A p.R452K | Missense Mutation (SNP) | VAF 21/111 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as rs376794336; called by muse, mutect2, varscan2
- TRABD2A | c.1267C>T p.R423W (on ENST00000409520 / NM_001277053.2; = p.R374W on NM_001080824.3) | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs1169030057, COSV52852134, COSV52878725; called by muse, mutect2, varscan2
- TRGC2 | c.7C>A p.Q3K | Missense Mutation (SNP) | VAF 48/216 reads (22%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs527629283; called by muse, mutect2, varscan2
- TRPM2 | c.2294T>G p.L765R | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100309059; called by muse, mutect2, varscan2
- UBE4B | c.2636C>T p.A879V (on ENST00000343090 / NM_001105562.3; = p.A750V on NM_006048.5) | Missense Mutation (SNP) | VAF 18/131 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.588); catalogued as rs770338844, COSV99477144; called by muse, mutect2, varscan2
- VPS41 | c.651G>T p.M217I | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT tolerated (0.3); PolyPhen benign (0.018); catalogued as COSV56069039, COSV99731113; called by muse, mutect2, varscan2
- ZFHX4 | c.188G>T p.G63V | Missense Mutation (SNP) | VAF 21/103 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as COSV99264875; called by muse, mutect2, varscan2
- ZNF680 | c.935A>G p.H312R | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs571358100, COSV100549242; called by muse, mutect2, varscan2
- AMBN | c.1128del p.S377Afs*10 | Frame Shift Del (DEL) | VAF 12/56 reads (21%) | called by mutect2, pindel, varscan2
- SEC24B | c.3333del p.H1112Ifs*2 | Frame Shift Del (DEL) | VAF 21/89 reads (24%) | called by mutect2, pindel, varscan2
- ALKBH7 | c.597C>G p.S199= | Silent (SNP) | VAF 16/61 reads (26%) | catalogued as rs753362202, COSV99831761; called by muse, mutect2, varscan2
- FAM98C | c.831C>T p.H277= | Silent (SNP) | VAF 34/148 reads (23%) | catalogued as rs372902479; called by muse, mutect2, varscan2
- FIBIN | c.444G>A p.Q148= | Silent (SNP) | VAF 10/56 reads (18%) | catalogued as rs181248433, COSV100590467; called by muse, mutect2, varscan2
- FLVCR2 | c.681G>A p.A227= | Silent (SNP) | VAF 35/271 reads (13%) | catalogued as rs143118396; called by muse, mutect2, varscan2
- GRIN2B | c.4179C>T p.D1393= | Silent (SNP) | VAF 9/53 reads (17%) | catalogued as rs199529615, COSV74206066, COSV74206481, COSV74206503; ClinVar: likely benign; called by muse, mutect2, varscan2
- HCN2 | c.1635C>T p.F545= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as rs762729967, COSV52113514, COSV52117181; called by mutect2, varscan2
- LNX1 | c.1137C>T p.S379= (on ENST00000263925 / NM_001126328.3; = p.S283= on NM_032622.2) | Silent (SNP) | VAF 26/126 reads (21%) | catalogued as rs1288458130, COSV99820196; called by muse, mutect2, varscan2
- LRP2 | c.11604C>T p.G3868= | Silent (SNP) | VAF 7/40 reads (18%) | catalogued as rs1429097267, COSV55546606; called by muse, mutect2, varscan2
- MMS22L | c.1707C>G p.L569= | Silent (SNP) | VAF 15/67 reads (22%) | catalogued as COSV99247306; called by muse, mutect2, varscan2
- MUC17 | c.4548A>G p.L1516= | Silent (SNP) | VAF 56/304 reads (18%) | catalogued as rs368847279; called by muse, mutect2, varscan2
- NAV2 | c.7360C>T p.L2454= (on ENST00000396087 / NM_001244963.2; = p.L2395= on NM_145117.5) | Silent (SNP) | VAF 16/103 reads (16%) | catalogued as COSV100217294; called by muse, mutect2, varscan2
- NLRP7 | c.2871G>A p.K957= (on ENST00000340844 / NM_206828.3; = p.K986= on NM_139176.3) | Silent (SNP) | VAF 35/109 reads (32%) | catalogued as COSV100052984; called by muse, mutect2, varscan2
- PANK4 | c.684G>T p.L228= | Silent (SNP) | VAF 16/69 reads (23%) | catalogued as COSV101022496; called by muse, mutect2, varscan2
- PAX1 | c.471C>T p.T157= | Silent (SNP) | VAF 14/70 reads (20%) | catalogued as COSV68271407; called by muse, mutect2, varscan2
- PPM1E | c.1122A>G p.E374= | Silent (SNP) | VAF 32/91 reads (35%) | catalogued as COSV100376402; called by muse, mutect2, varscan2
- PTPRZ1 | c.237A>G p.K79= | Silent (SNP) | VAF 17/69 reads (25%) | catalogued as COSV101100439; called by muse, mutect2, varscan2
- RHOBTB1 | c.1449G>A p.T483= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as rs761872807, COSV61960402; called by mutect2, varscan2
- SASH1 | c.912C>T p.S304= | Silent (SNP) | VAF 12/55 reads (22%) | catalogued as rs111245321, COSV66562015; called by muse, mutect2, varscan2
- SBF2 | c.168G>T p.L56= | Silent (SNP) | VAF 13/62 reads (21%) | catalogued as COSV99814894; called by muse, mutect2, varscan2
- SDK2 | c.4785C>T p.Y1595= | Silent (SNP) | VAF 6/56 reads (11%) | catalogued as rs141328074; called by mutect2, varscan2
- SPSB4 | c.684C>T p.N228= | Silent (SNP) | VAF 11/49 reads (22%) | catalogued as rs768764654, COSV100141553; called by muse, mutect2, varscan2
- ZNF536 | c.3447C>A p.I1149= | Silent (SNP) | VAF 12/73 reads (16%) | catalogued as COSV100835455, COSV62836506; called by muse, mutect2, varscan2
- CPSF6 | c.*3699T>A | 3'UTR (SNP) | VAF 8/49 reads (16%) | catalogued as COSV99879514; called by muse, mutect2, varscan2
